Somatic mutation profile of tumor specimen ALCH-B2FH-TTP1-A (aliquot ALCH-B2FH-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B2FH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Age at diagnosis: 67.5 years (24,656 days).
Specimen ALCH-B2FH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa0d6d62-472f-48ab-b29c-520342eff565.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2FH-NB1-A (Blood Derived Normal), aliquot ALCH-B2FH-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e660194-d603-48d9-83ef-6ffaac8a434a

The open-access MAF lists 190 somatic variants for this specimen: 143 protein-altering or splice-affecting, 28 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 28, Nonsense Mutation 16, Intron 14, Frame Shift Del 5, Frame Shift Ins 3, Splice Site 3, Translation Start Site 2, Splice Region 2, 5'UTR 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/369 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TRAPPC9 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 101/273 reads (37%) | catalogued as rs267607136, CM099332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.1841C>A p.S614* | Nonsense Mutation (SNP) | VAF 39/136 reads (29%) | catalogued as COSV59383530; called by muse, mutect2, varscan2
- ANKRD30B | c.1670C>A p.A557E | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100746270; called by muse, mutect2, varscan2
- ANKRD36B | c.1337T>C p.I446T | Missense Mutation (SNP) | VAF 51/386 reads (13%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.506); catalogued as rs536603130; called by muse, mutect2, varscan2
- ANKRD6 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs200814043; called by mutect2, varscan2
- ASAH1 | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as rs1400874100; called by muse, mutect2
- BRPF3 | c.3557C>T p.A1186V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1363623097, COSV100325570; called by muse, mutect2
- CNTN2 | c.1110+7G>A | Splice Region (SNP) | VAF 14/96 reads (15%) | catalogued as rs1467779870; called by muse, mutect2, varscan2
- CPS1 | c.2717G>A p.R906K | Missense Mutation (SNP) | VAF 61/397 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99241572; called by muse, mutect2, varscan2
- DCST2 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs138904334; called by muse, mutect2, varscan2
- ERBB4 | c.545del p.G182Vfs*27 | Frame Shift Del (DEL) | VAF 71/195 reads (36%) | catalogued as COSV53573166; called by mutect2, pindel, varscan2
- ESPL1 | c.3127G>A p.D1043N | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as COSV57759119; called by muse, mutect2, varscan2
- FAT3 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53117239; called by muse, mutect2, varscan2
- GABRA3 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 76/122 reads (62%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs757929750, COSV64803511; called by muse, mutect2, varscan2
- GLG1 | c.1843C>G p.R615G | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.308); catalogued as COSV52670048; called by muse, mutect2
- GRIN2D | c.2323C>T p.L775F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763528141; called by muse, mutect2, varscan2
- HAPLN2 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750476459, COSV54815277; called by muse, mutect2, varscan2
- HOMER2 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs544469522; called by muse, mutect2, varscan2
- IFFO1 | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs1404371925; called by muse, mutect2, varscan2
- KCNH7 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 89/213 reads (42%) | catalogued as COSV59802840; called by muse, mutect2, varscan2
- MTCL1 | c.1665A>T p.E555D (on ENST00000306329 / NM_001378206.1; = p.E195D on NM_015210.4) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV60402629; called by muse, mutect2, varscan2
- MUC6 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as rs769689568; called by mutect2, varscan2
- MUL1 | c.61G>T p.V21F | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.04); catalogued as COSV51641358; called by muse, mutect2, varscan2
- MYO15A | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs1213311182; called by muse, varscan2
- NEGR1 | c.628T>A p.S210T | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs975978821; called by muse, mutect2, varscan2
- NLGN4Y | c.1754C>T p.T585M | Missense Mutation (SNP) | VAF 129/231 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1301916464; called by muse, mutect2, varscan2
- OR10A4 | c.653C>G p.S218C | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65841884; called by muse, mutect2, varscan2
- OR2AG2 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs960059944, COSV58455951; called by muse, mutect2, varscan2
- OR4A5 | c.485G>C p.S162T | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.035); catalogued as COSV60521991; called by muse, mutect2, varscan2
- OR8I2 | c.809C>A p.A270E | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV56166494, COSV56170718; called by muse, mutect2, varscan2
- PAPPA2 | c.1198A>G p.M400V | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as rs773074290, COSV62787961; called by muse, mutect2, varscan2
- PARD3B | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | catalogued as rs766875287, COSV100593350, COSV62506538; called by muse, mutect2
- PDXDC1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as rs368974427, COSV57903259; called by muse, mutect2, varscan2
- PNMA2 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV72908503; called by muse, mutect2, varscan2
- PPFIA2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100332743, COSV61058087; called by muse, mutect2, varscan2
- PRICKLE1 | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs936545109, COSV58209090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM10 | c.1975del p.A659Pfs*45 | Frame Shift Del (DEL) | VAF 40/116 reads (34%) | catalogued as COSV100237811; called by mutect2, pindel, varscan2
- RYR1 | c.14203C>T p.R4735W | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.936); catalogued as rs766887342, COSV62095285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.7090C>A p.P2364T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV63696165; called by muse, mutect2, varscan2
- SI | c.4950C>A p.Y1650* | Nonsense Mutation (SNP) | VAF 274/431 reads (64%) | catalogued as COSV52274232; called by muse, mutect2, varscan2
- SLAIN1 | c.1092C>G p.S364R (on ENST00000466548; = p.S101R on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV99935025; called by muse, mutect2, varscan2
- SLC38A2 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 74/279 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as COSV99873952; called by muse, mutect2, varscan2
- STK11 | c.558del p.G187Vfs*100 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as COSV58827581; called by mutect2, pindel, varscan2
- STK16 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs768704830; called by muse, mutect2, varscan2
- SULT6B1 | c.250A>G p.K84E (on ENST00000535679 / NM_001367551.1; = p.K46E on NM_001032377.2) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs767937499, COSV53193322, COSV99573385; called by muse, mutect2, varscan2
- TIMD4 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as rs375659101; called by muse, mutect2, varscan2
- TTBK2 | c.3542C>T p.S1181L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs748766632, COSV51157748; called by muse, mutect2, varscan2
- UNC5CL | c.737G>A p.W246* | Nonsense Mutation (SNP) | VAF 17/113 reads (15%) | catalogued as rs1425517094; called by muse, mutect2, varscan2
- VSTM4 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.089); catalogued as rs563816877, COSV53677039; called by muse, mutect2, varscan2
- ABCA7 | c.4724C>T p.S1575F | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ADAMTS20 | c.1943-9_1945del p.X648_splice | Splice Site (DEL) | VAF 14/78 reads (18%) | called by mutect2, pindel
- ADGRG4 | c.1276G>T p.G426W | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ANKRD50 | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 91/194 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- B4GALNT1 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- B4GALNT3 | c.447+1G>A p.X149_splice | Splice Site (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- C17orf107 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- C5orf49 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- CACNA1I | c.847A>T p.I283F | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CAMTA1 | c.3872A>G p.E1291G | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CCDC62 | c.1060A>T p.K354* | Nonsense Mutation (SNP) | VAF 28/184 reads (15%) | called by muse, mutect2
- CFAP46 | c.4324A>C p.S1442R | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CHGB | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 106/204 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.073); called by muse, varscan2
- CHRNE | c.1156C>A p.L386M | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- CNTNAP3 | c.3601G>A p.A1201T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL3A1 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 61/412 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- COL6A3 | c.4843C>T p.P1615S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, varscan2
- CRYBG3 | c.1834A>C p.K612Q | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CYLD | c.1242_1245dup p.F416Qfs*63 | Frame Shift Ins (INS) | VAF 74/266 reads (28%) | called by mutect2, pindel, varscan2
- DCAF11 | c.1414A>C p.S472R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- DCDC1 | c.1454dup p.N485Kfs*11 | Frame Shift Ins (INS) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- DDX19B | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 76/190 reads (40%) | called by muse, mutect2, varscan2
- DDX43 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DDX46 | c.2171C>T p.T724I | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- DIDO1 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAAF6 | c.641T>C p.F214S | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2
- DNAH5 | c.13820A>G p.Q4607R | Missense Mutation (SNP) | VAF 48/399 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ERCC4 | c.584+4A>G | Splice Region (SNP) | VAF 17/270 reads (6%) | called by muse, mutect2
- FCGBP | c.12515G>A p.G4172E | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLNC | c.2422G>T p.G808C | Missense Mutation (SNP) | VAF 16/253 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- GGT7 | c.697C>A p.P233T | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GIMAP4 | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GK2 | c.736G>T p.G246* | Nonsense Mutation (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- GLI3 | c.4282C>A p.Q1428K | Missense Mutation (SNP) | VAF 261/525 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HEPH | c.620A>G p.K207R (on ENST00000343002; = p.K261R on NM_138737.5) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.582); called by muse, varscan2
- HERC1 | c.13597A>C p.T4533P | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HS3ST2 | c.923C>A p.T308N | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HSD11B1 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 13/329 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); called by muse, mutect2
- ITGA4 | c.902A>T p.K301M | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- KANK4 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ2 | c.742A>C p.I248L | Missense Mutation (SNP) | VAF 69/479 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LSM6 | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2
- MAGEA8 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MB21D2 | c.1010T>A p.L337H | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MUC17 | c.10913C>A p.T3638N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYBPC1 | c.2504-1G>T p.X835_splice (on ENST00000550270 / NM_206820.2; = p.X842_splice on NM_002465.4) | Splice Site (SNP) | VAF 118/435 reads (27%) | called by muse, mutect2, varscan2
- MYEF2 | c.370G>T p.V124F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- NALCN | c.2707A>C p.M903L | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NCKAP1 | c.1900_1914del p.A634_S638del | In Frame Del (DEL) | VAF 20/151 reads (13%) | called by mutect2, pindel
- NFE2L2 | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- OR2L2 | c.259G>T p.G87* | Nonsense Mutation (SNP) | VAF 79/171 reads (46%) | called by muse, mutect2, varscan2
- PCDH10 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- PHKA2 | c.3421G>T p.V1141L | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- PIK3C2G | c.1819G>A p.A607T (on ENST00000676171; = p.A566T on NM_004570.5) | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLA2G4F | c.489G>C p.K163N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2
- PML | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- POLR2M | c.41A>G p.E14G | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PRDM13 | c.223A>T p.R75* | Nonsense Mutation (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- PRKY | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSMA1 | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PTAR1 | c.202G>T p.V68F | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- QRICH2 | c.1825G>A p.G609R | Missense Mutation (SNP) | VAF 20/247 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2
- RASGRP3 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 141/244 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RBL1 | c.740G>A p.C247Y | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RBM19 | c.1729T>G p.F577V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIT1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 12/144 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); called by muse, mutect2
- RNF121 | c.40G>T p.A14S | Missense Mutation (SNP) | VAF 110/182 reads (60%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- RP1 | c.5096A>G p.E1699G | Missense Mutation (SNP) | VAF 102/429 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RPAP3 | c.934_941del p.D312* | Frame Shift Del (DEL) | VAF 24/142 reads (17%) | called by mutect2, pindel, varscan2
- RPL8 | c.207dup p.K70* | Frame Shift Ins (INS) | VAF 31/137 reads (23%) | called by mutect2, pindel, varscan2
- SALL1 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- SBF2 | c.3682A>C p.S1228R | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- SDK1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- SOCS6 | c.932C>A p.S311* | Nonsense Mutation (SNP) | VAF 30/285 reads (11%) | called by muse, mutect2, varscan2
- SOWAHC | c.654G>T p.R218S | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SRP72 | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- STAG1 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- STAT1 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 103/490 reads (21%) | called by muse, mutect2, varscan2
- SUPT5H | c.2300G>T p.R767M | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TCF20 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TFE3 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TP53 | c.916_917del p.R306Sfs*30 | Frame Shift Del (DEL) | VAF 106/232 reads (46%) | called by mutect2, pindel, varscan2
- TPO | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRIO | c.8743G>T p.D2915Y | Missense Mutation (SNP) | VAF 107/239 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSSK2 | c.955A>C p.T319P | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBL5 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.194); called by muse, varscan2
- UGT1A3 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- VEPH1 | c.863G>C p.G288A | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZCCHC14 | c.1964C>G p.T655S (on ENST00000268616; = p.T792S on NM_015144.3) | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZDBF2 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- ZNF14 | c.1371G>T p.R457S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF503 | c.530C>G p.P177R | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF613 | c.438C>A p.N146K (on ENST00000293471 / NM_001031721.4; = p.N110K on NM_024840.4) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ADGRG4 | c.1275T>C p.T425= | Silent (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- ANXA6 | c.657G>C p.L219= | Silent (SNP) | VAF 80/158 reads (51%) | catalogued as COSV100636980; called by mutect2, varscan2
- C19orf81 | c.372C>T p.V124= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- CHRNE | c.957C>T p.V319= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as rs1244564448; called by muse, mutect2, varscan2
- DDX5 | c.465C>T p.H155= | Silent (SNP) | VAF 10/260 reads (4%) | catalogued as rs552282171; called by muse, mutect2
- FBRSL1 | c.2673G>T p.P891= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV55512235; called by muse, mutect2, varscan2
- FNDC7 | c.2061G>C p.G687= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as rs1209333935; called by muse, mutect2, varscan2
- GPER1 | c.660G>T p.T220= | Silent (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- HELZ2 | c.4626C>T p.G1542= (on ENST00000467148 / NM_001037335.2; = p.G973= on NM_033405.3) | Silent (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2, varscan2
- HSPA1L | c.606G>T p.L202= | Silent (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- KANK4 | c.510G>T p.L170= | Silent (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- KCNMA1 | c.195G>A p.K65= | Silent (SNP) | VAF 56/298 reads (19%) | called by muse, varscan2
- LAG3 | c.1476T>C p.P492= | Silent (SNP) | VAF 20/182 reads (11%) | called by muse, varscan2
- LOXHD1 | c.3258G>C p.L1086= | Silent (SNP) | VAF 35/168 reads (21%) | called by muse, mutect2, varscan2
- MRGPRX4 | c.207C>T p.A69= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs143611694, COSV100049672; called by muse, mutect2, varscan2
- MYCBP2 | c.11262C>T p.A3754= (on ENST00000357337; = p.A3792= on NM_015057.5) | Silent (SNP) | VAF 34/102 reads (33%) | called by muse, mutect2, varscan2
- MYRF | c.2145C>G p.L715= (on ENST00000278836 / NM_001127392.3; = p.L706= on NM_013279.4) | Silent (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- OR4C6 | c.138T>C p.T46= | Silent (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- PLPPR4 | c.1599G>A p.L533= | Silent (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- RYR2 | c.6861C>T p.D2287= | Silent (SNP) | VAF 147/350 reads (42%) | catalogued as COSV63711460; called by muse, mutect2, varscan2
- SPTA1 | c.5019G>A p.L1673= | Silent (SNP) | VAF 90/460 reads (20%) | called by muse, mutect2, varscan2
- STARD9 | c.5763G>C p.L1921= | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- TPSG1 | c.585C>T p.D195= | Silent (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2
- UGGT1 | c.1179C>G p.L393= | Silent (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- VCAN | c.8223G>A p.L2741= | Silent (SNP) | VAF 84/177 reads (47%) | catalogued as rs762244250, COSV54117224; called by muse, mutect2, varscan2
- XYLT1 | c.2811C>A p.A937= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV99763248; called by muse, varscan2
- XYLT1 | c.2733C>A p.G911= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs377724066; called by muse, varscan2
- ZNF559 | c.63G>T p.V21= | Silent (SNP) | VAF 106/229 reads (46%) | called by muse, mutect2, varscan2
- ABHD3 | c.555+407C>G | Intron (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- ADCYAP1R1 | c.1047-3077G>T | Intron (SNP) | VAF 19/137 reads (14%) | called by muse, mutect2, varscan2
- ANAPC1P4 | n.1123A>T | RNA (SNP) | VAF 23/346 reads (7%) | called by muse, mutect2
- AP000769.3 | chr11:65501965 T>G | 5'Flank (SNP) | VAF 33/114 reads (29%) | called by muse, mutect2, varscan2
- CACNB2 | c.213+110290T>A | Intron (SNP) | VAF 50/235 reads (21%) | catalogued as rs1237399505; called by muse, mutect2, varscan2
- CCNYL2 | n.836-1770C>A | Intron (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- CDH2 | c.173-22577G>T | Intron (SNP) | VAF 18/139 reads (13%) | called by muse, mutect2, varscan2
- CHCHD3 | c.170-10455T>C | Intron (SNP) | VAF 37/232 reads (16%) | called by muse, mutect2, varscan2
- CYBA | c.204-25C>T | Intron (SNP) | VAF 17/107 reads (16%) | catalogued as rs575341053; called by muse, mutect2, varscan2
- DST | c.4297-1497A>G | Intron (SNP) | VAF 12/190 reads (6%) | catalogued as rs1319068420; called by muse, mutect2
- FOXL2 | c.-24C>T | 5'UTR (SNP) | VAF 12/48 reads (25%) | catalogued as rs1246302647; called by muse, mutect2, varscan2
- GRM7 | c.1034-11888C>T | Intron (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- KBTBD2 | c.-17A>G | 5'UTR (SNP) | VAF 41/132 reads (31%) | catalogued as rs761935530; called by muse, mutect2, varscan2
- NEXN | c.*101C>A | 3'UTR (SNP) | VAF 63/325 reads (19%) | called by muse, mutect2, varscan2
- PHF20L1 | c.722-27C>G | Intron (SNP) | VAF 21/436 reads (5%) | called by muse, mutect2
- RBFOX1 | c.414+166423G>A | Intron (SNP) | VAF 76/186 reads (41%) | called by muse, mutect2, varscan2
- SFTPB | c.393+21T>A | Intron (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12802G>T | Intron (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- TEX51 | c.274+11C>T | Intron (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
